Somatic mutation profile of tumor specimen ALCH-B2MP-TTP1-A (aliquot ALCH-B2MP-TTP1-A-1-0-D-A777-36) from ALCHEMIST case ALCH-B2MP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.1 years (23,046 days).
Specimen ALCH-B2MP-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45769e1a-bbff-4ab2-b02e-b33405136a00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2MP-NB1-A (Blood Derived Normal), aliquot ALCH-B2MP-NB1-A-1-0-D-A777-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/420f9677-bc9d-4cd1-8ac1-b6df37fa7c7b

The open-access MAF lists 36 somatic variants for this specimen: 26 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 8, Nonsense Mutation 4, 5'UTR 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 74/702 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, varscan2
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 24/376 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2
- ANKFN1 | c.63-1G>A p.X21_splice | Splice Site (SNP) | VAF 12/102 reads (12%) | catalogued as COSV59454428; called by muse, mutect2, varscan2
- ATG4B | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 8/171 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs1256956340; called by muse, mutect2
- COL7A1 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 16/407 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs966257558, CX095173, COSV60394266; called by muse, mutect2
- MARCHF11 | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 56/448 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.025); catalogued as rs1446576819, COSV60126799; called by muse, mutect2, varscan2
- MUC12 | c.2794T>A p.S932T (on ENST00000379442; = p.S789T on NM_001164462.1) | Missense Mutation (SNP) | VAF 34/1960 reads (2%) | SIFT tolerated (0.12); PolyPhen benign (0.159); catalogued as rs1255105003; called by muse, mutect2
- OTOF | c.1684G>T p.G562C | Missense Mutation (SNP) | VAF 16/516 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55501594; called by muse, mutect2
- PER1 | c.3110C>G p.S1037C | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV57918322; called by muse, mutect2
- RBM10 | c.2458G>T p.E820* | Nonsense Mutation (SNP) | VAF 32/470 reads (7%) | catalogued as COSV61309648; called by muse, mutect2
- RBM28 | c.2194C>T p.Q732* | Nonsense Mutation (SNP) | VAF 38/510 reads (7%) | catalogued as rs541618813; called by muse, mutect2
- RLIM | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV60325116; called by muse, mutect2
- SND1 | c.1085C>G p.S362* | Nonsense Mutation (SNP) | VAF 38/567 reads (7%) | catalogued as COSV61240538; called by muse, mutect2
- TRIOBP | c.6955G>A p.G2319R (on ENST00000644935 / NM_001039141.3; = p.G606R on NM_007032.5) | Missense Mutation (SNP) | VAF 19/511 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100730809; called by muse, mutect2
- TSNARE1 | c.1118G>A p.R373K | Missense Mutation (SNP) | VAF 18/382 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as COSV100210052; called by muse, mutect2
- BEGAIN | c.705C>A p.C235* | Nonsense Mutation (SNP) | VAF 13/304 reads (4%) | called by muse, mutect2
- FAM135A | c.466T>G p.F156V (on ENST00000370479 / NM_001351599.1; = p.F113V on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/766 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- GAD1 | c.1459G>C p.A487P | Missense Mutation (SNP) | VAF 34/704 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NSMCE2 | c.670G>T p.D224Y | Missense Mutation (SNP) | VAF 54/301 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- PIK3C2G | c.2104T>A p.S702T (on ENST00000676171; = p.S661T on NM_004570.5) | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.995); called by muse, mutect2
- PLEKHG4 | c.1456G>T p.D486Y | Missense Mutation (SNP) | VAF 12/361 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2
- RO60 | c.708G>T p.K236N | Missense Mutation (SNP) | VAF 26/408 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SFRP1 | c.288C>G p.S96R | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2
- SLC12A7 | c.781C>T p.L261F | Missense Mutation (SNP) | VAF 36/816 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.087); called by muse, mutect2
- TASOR | c.1795G>A p.D599N (on ENST00000355628 / NM_001365636.2; = p.D203N on NM_015224.3) | Missense Mutation (SNP) | VAF 12/330 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.778); called by muse, mutect2
- ZSCAN12 | c.1783G>C p.E595Q | Missense Mutation (SNP) | VAF 18/386 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- ADAMTS12 | c.3888G>A p.E1296= | Silent (SNP) | VAF 18/456 reads (4%) | called by muse, mutect2
- CCM2 | c.685C>T p.L229= | Silent (SNP) | VAF 16/516 reads (3%) | catalogued as COSV99347826; called by muse, mutect2
- GRIA1 | c.1914G>A p.L638= | Silent (SNP) | VAF 48/910 reads (5%) | catalogued as COSV53592025; called by muse, mutect2
- HAND2 | c.393C>T p.A131= | Silent (SNP) | VAF 37/664 reads (6%) | catalogued as rs372782210; called by muse, mutect2
- KANSL3 | c.2409C>G p.V803= (on ENST00000666923 / NM_001349262.2; = p.V777= on NM_001115016.3) | Silent (SNP) | VAF 12/200 reads (6%) | called by muse, mutect2
- OGT | c.1155G>A p.K385= | Silent (SNP) | VAF 10/242 reads (4%) | called by muse, mutect2
- PHRF1 | c.336C>G p.L112= | Silent (SNP) | VAF 12/350 reads (3%) | catalogued as COSV52763999; called by muse, mutect2
- SOBP | c.1641C>T p.S547= | Silent (SNP) | VAF 16/348 reads (5%) | catalogued as COSV100433189; called by muse, mutect2
- FUT8 | c.-326+155C>G | Intron (SNP) | VAF 15/384 reads (4%) | called by muse, mutect2
- MRPL3 | c.-92A>G | 5'UTR (SNP) | VAF 18/161 reads (11%) | catalogued as rs749030024; called by muse, mutect2, varscan2
